Somatic mutation profile of tumor specimen TCGA-05-4433-01A (aliquot TCGA-05-4433-01A-22D-1855-08) from TCGA case TCGA-05-4433, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 82.7 years (30,194 days).
Specimen TCGA-05-4433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76e5dd02-95cd-4e1b-a79b-9a4a9a5bd4d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4433-10A (Blood Derived Normal), aliquot TCGA-05-4433-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab706b48-1249-48d6-8297-c1eb62617c6d

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Ins 3, Intron 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs914877431, COSV67129674; called by muse, mutect2, varscan2
- ANKDD1A | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60352905; called by muse, mutect2, varscan2
- COL4A2 | c.3836C>T p.A1279V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.474); catalogued as COSV64627780; called by muse, mutect2, varscan2
- CYP2A6 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs372113929; called by muse, mutect2, varscan2
- DNMT3B | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as rs768468807, COSV52417928, COSV52423180; called by muse, mutect2, varscan2
- DUOX2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.67); catalogued as COSV50993424; called by muse, mutect2, varscan2
- FBXO10 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52832727; called by muse, mutect2, varscan2
- FBXO34 | c.1454dup p.L485Ffs*15 | Frame Shift Ins (INS) | VAF 37/138 reads (27%) | catalogued as rs759373712; called by mutect2, varscan2
- GPR45 | c.1094G>A p.C365Y | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV51523685; called by muse, mutect2, varscan2
- KDM5B | c.4267C>G p.R1423G | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs751400477, COSV52507308, COSV52508150; called by muse, mutect2, varscan2
- METTL14 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66310541; called by muse, mutect2, varscan2
- MEX3B | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1420740667, COSV61663330; called by muse, mutect2, varscan2
- MORC3 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV68688301; called by muse, mutect2
- MYH7B | c.651C>T p.T217= | Splice Region (SNP) | VAF 8/38 reads (21%) | catalogued as rs773450665, COSV53419477; called by muse, mutect2, varscan2
- NDUFV1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs779402114, COSV59595272; called by muse, mutect2, varscan2
- NEDD8 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99164615; called by muse, mutect2, varscan2
- NUP43 | c.726G>T p.L242F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs372876390, COSV61189737; called by muse, mutect2, varscan2
- PCSK6 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376291078; called by muse, mutect2, varscan2
- PLCL1 | c.2116T>G p.Y706D | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV70828983; called by muse, mutect2, varscan2
- PRMT7 | c.1784G>A p.C595Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs762559370, COSV54711931; called by muse, mutect2
- SIK2 | c.1668A>T p.R556S | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV59251978; called by muse, mutect2, varscan2
- SLC50A1 | c.70T>G p.S24A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as COSV100310313; called by muse, mutect2, varscan2
- SPATA31A1 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 160/863 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1259955199, COSV66533393; called by muse, mutect2, varscan2
- UPF2 | c.3687A>T p.Q1229H | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62660338; called by muse, mutect2, varscan2
- XRN1 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs777191632, COSV53810671; called by muse, mutect2, varscan2
- ZNF536 | c.1224C>A p.D408E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62823347; called by muse, mutect2, varscan2
- JAG1 | c.740_741dup p.P248Sfs*165 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- ZSWIM8 | c.1016dup p.R340Efs*4 | Frame Shift Ins (INS) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- CLVS1 | c.921C>T p.H307= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs372058481; called by muse, mutect2, varscan2
- HMX2 | c.87C>T p.G29= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs749490178, COSV100378733; called by muse, mutect2, varscan2
- MEFV | c.402G>A p.P134= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54821281; called by muse, mutect2, varscan2
- NAA11 | c.666A>G p.S222= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54513958; called by muse, mutect2, varscan2
- NRN1 | c.18C>T p.N6= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as rs144443923, COSV99784123; called by muse, mutect2, varscan2
- OR8H1 | c.183T>C p.F61= | Silent (SNP) | VAF 91/239 reads (38%) | catalogued as COSV100477026; called by muse, mutect2, varscan2
- SLITRK1 | c.1936C>A p.R646= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV65674040, COSV65675357; called by muse, mutect2, varscan2
- TAL1 | c.582C>T p.S194= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV53745023, COSV53746341; called by muse, mutect2, varscan2
- USH2A | c.14298T>C p.S4766= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV56362992; called by muse, mutect2, varscan2
- FARP1 | c.171+31124C>T | Intron (SNP) | VAF 15/60 reads (25%) | catalogued as rs768033279, COSV60333927; called by muse, mutect2, varscan2
